Surgical pathology report (de-identified scan), TCGA case TCGA-XQ-A8TB, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University of Sao Paulo, specimen TCGA-XQ-A8TB-01A (Primary Tumor).

ICD-O-3

Adenocarcinoma NOS
8140/3

Site: Prostate NOS
C61.9

Spw 1/29/14

Nature of material: Prostate

Received on:

ANATOMOPATHOLOGIC RESULT

MACROSCOPY

Received three vials:

- 1 - "Prostate": specimen consisting of prostate, seminal vesicles and vas deferens. The prostate weighs 45.0 g and measures 5.5 cm in side axis, 4.1 cm in the craniocaudal axis and 4.0 cm in the anteroposterior axis. To the cuts, the prostate presents firm and clear-brown parenchyma with sketches of nodules in the central portions. The right seminal vesicle measures 2.5 x 1.1 x 0.9 cm and left, 2.1 x 1.3 x 1.2 cm. The right vas deferens measures 1.1 cm long and 0.5 cm in diameter, and the left, 0.9 cm long and 0.5 cm in diameter.
- 2 - "Right lymphatic chain": irregular fragment of fibrofatty tissue measuring 5.1 x 2.1 x 0.9 cm. Two lymph nodes were dissected measuring 0.5 and 3.1 cm in greatest axis.
- 3 - "Left lymphatic chain": irregular fragment of fibrofatty tissue measuring 4.2 x 2.1 x 1.5 cm. Two lymph nodes were dissected measuring 0.5 and 3.5 cm in greatest axis.

MICROSCOPY

Description dispensable.

DIAGNOSTIC

Product of radical prostatectomy and bilateral obturator lymphadenectomy:

- Prostatic usual acinar adenocarcinoma, Gleason: 4 + 5 = 9, involving widely apex, middle third and bottom of right and left lobes.
- Urethral margin compromised by neoplasia.
- Presence of neoplasm distant 1.0 mm from bladder margin.
- Circumferential margin compromised by neoplasia in the right apex, left apex and left middle third.
- Presence of extraprostatic extension of the tumor in the left base.
- Presence of perineural infiltration foci.
- Angiolymphatic invasion undetected.
- Presence of neoplastic infiltration of the left seminal vesicle.
- Right seminal vesicle and vas deferens free of infiltration.
- Four dissected lymph nodes, from right (2 nodes) and left obturator chains (2 nodes) free of metastases.
- Pathological staging: pT3b, pN0 (TNM - 7th edition).
- Non-neoplastic prostatic parenchyma with nodular hyperplasia of the prostate gland - stroma-glandular type.

PARTICIPANTS OF APPRAISAL REPORT

- ISSUER

HIPAA (discrepancy)		

Source: NCI Genomic Data Commons file 00bbb7c9-9a45-4944-a3e5-4f436a00e552 (TCGA-XQ-A8TB.EDF35290-BD43-4527-A8BF-ED6F3CC1F0AB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).